Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACQ7, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACQ7-TTP1-A (Primary Tumor).

[page 1 of 2]
Sample sent as:

1. Posterior segment neoplasm of the right upper lobe, surgical ode n8, surgical biopsy

Macroscopic report:

1. Fragment of pulmonary parenchyma of cm 5x4x2 containing to the cut a subpleural nodule of cm 2.3x1.2x1.4 ; with polycyclic margins consists of gray grainy tissue
2. Multiple anthracotic fragments for a volume of cc 1.5

Microscopic report:

1. The extensive sampling carried out lung parenchyma evidence place of neoplastic epithelial proliferation with adenocarcinoma characters.
The tumor infiltrates extensively the lung parenchyma to the visceral pleura, with out, however, to determine frank infiltration.
There are large areas with growth type bronchiole alveolar mucinous pattern and non-mucinous with micropapillary aspects.
Neoplastic nests are also in the surrounding lung parenchyma.
Non-neoplastic lung parenchyma has bronchitis respiratory health. No evidence of vascular invasion intra and / or peritumoral.
The determined nuclear proliferation index with the antibody Mib1 (K167) is approximately equal to 10%, the p53 protein is expressed in scattered neoplastic nuclei
2. The lymph node n8 is anthracotic and negative for malignancy

Findings and histopathological diagnosis

Per TSS, no histological subtypes available. P

1. Adenocarcinoma infiltrating the lung parenchyma and associated with large areas of such growth bronchiole alveolar mucinous carcinoma pattern and non-mucinous pattern.
2. Anthracotic lymph node

Clinical data:

Bronchoscopy of right pulmonary nodule: chronic inflammation, cancer?

Sample sent as:

Bronchoscopy biopsy: peripheral right bronchus

ICB-0-3

adenocarcinoma, NOS 8140/3

Site: (R) lung, upper lobe C34.1

Macroscopic report:

A minute biopsy frustule

ICB-10

C 34.11

*hw
12/16/10*

Microscopic report:

Frustules of bronchial mucosa seat of carcinoma proliferation with acinar and alveolar bronchiole architecture; it composed of cylindrical cells, with round-oval nucleus, sometimes evident nucleolus and cytoplasm with vacuoles above and below nuclear, that configure an adenocarcinoma-like appearance of fetal type.

[page 2 of 2]
Clinical data:

Bronchoscopy of right pulmonary nodule: chronic inflammation, cancer?

Sample sent as:

Bronchoscopy biopsy: peripheral right bronchus

Macroscopic report:

A minute biopsy frustule

Microscopic report:

Frustules of bronchial mucosa seat of carcinoma proliferation with acinar and alveolar bronchiole architecture; it composed of cylindrical cells, with round-oval nucleus, sometimes evident nucleolus and cytoplasm with vacuoles above and below nuclear, that configure an adenocarcinoma-like appearance of fetal type.

Findings and histopathological diagnosis

Adenocarcinoma

Source: NCI Genomic Data Commons file a01931ae-8ded-413f-928e-77f8e6752616 (CDDP-ACQ7-TTP1.BB15EF47-8D43-4C87-93DC-42DD5952D7C9.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).